Somatic mutation profile of tumor specimen TCGA-EM-A4FR-01A (aliquot TCGA-EM-A4FR-01A-11D-A257-08) from TCGA case TCGA-EM-A4FR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.2 years (10,316 days).
Specimen TCGA-EM-A4FR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00491165-cfb2-41af-9c25-ba33fe3c666e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A4FR-10A (Blood Derived Normal), aliquot TCGA-EM-A4FR-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f13020c-a897-4764-8800-9b2987935731

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.6755C>T p.S2252F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV53138464, COSV99497546; called by muse, mutect2, varscan2
- CLSTN2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs375249688; called by muse, mutect2
- KIF25 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV63028211; called by muse, mutect2, varscan2
- SNRNP48 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV60940309; called by muse, mutect2, varscan2
